Surgical pathology report (de-identified scan), TCGA case TCGA-73-4666, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-73-4666-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. 4R RIGHT DISTAL PARATRACHEAL
B. 4L LEFT DISTAL PARATRACHEAL
C. LEVEL 7
D. 2R RIGHT PROXIMAL PARATRACHEAL
E. RIGHT UPPER LOBE

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Non-small cell cancer of right upper lobe lung

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA/FSB/FSC/FSD-lymph nodes negative for tumor called by [REDACTED]
p.m.

FSE: Right upper Lobe: Bronchial margin-Negative for Carcinoma. Diagnosis called to Dr. [REDACTED]

GROSS DESCRIPTION:

A. 4R RIGHT DISTAL PARATRACHEAL

Received fresh are two anthracotic soft tissue fragments, 0.5 x 0.4 x 0.1 cm and 0.6 x 0.4 x 0.1 cm. Submitted entirely for frozen section diagnosis in cassette FSA.

B. 4L LEFT DISTAL PARATRACHEAL

Received fresh are 3 anthracotic soft tissue fragments, 0.5, 0.3, and 0.2 cm in greatest dimension. Submitted entirely for frozen section diagnosis in cassette FSB.

C. LEVEL 7

Received fresh are 3 anthracotic soft tissue fragments, 0.3, 0.2, 0.2 cm in greatest dimension. Submitted entirely for frozen section diagnosis in cassette FSC.

D. 2R RIGHT PROXIMAL PARATRACHEAL

[page 2 of 4]
Received fresh are two anthracotic soft tissue fragment, 0.7 x 0.3 x 0.2 cm and 0.3 x 0.1 by less than 0.1-cm. Submitted entirely for frozen section diagnosis in cassette FSD.

E. RIGHT UPPER LOBE

Received fresh 16.0 x 14.0 x 3.0cm. The pleural surface is gray purple and remarkable for a palpable nodule. This area is inked Black. A gray white discolored area is also noted on the pleural surface 3.4 x 2.0 cm. The bronchial margin is shaved and submitted in FSE. The specimen is serially sectioned to reveal a gray white well circumscribed mass 2.0 x 1.7 x 1.5 cm, 0.4 cm from the pleural surface and 4.0 cm from the bronchial margin. Five hilar lymph nodes are identified ranging from 0.3 x 0.2 x 0.2 cm to 0.9 x 0.7 x 0.6 cm. Multiple palpable nodular areas are identified abutting the pleural surface, 0.4cm in greatest dimension. The remainder of the lung parenchyma is unremarkable. Representative sections are submitted as follows:

FSE: bronchial margin

E2: 4 lymph nodes

E3: 1 lymph node

E4-E6: mass with pleural surface

E7-E9: gray discolored area on pleural surface

E10-E14: nodular areas

E15: uninvolved parenchyma

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Specimen E

Population: Tumor Cells

Stain/Marker:	Result:	Comment:
MUCIN STAIN	Positive	

Material: Block E4

Population: Tumor Cells

Stain/Marker:	Result:	Comment:
MUCIN STAIN	Positive	

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

- A. LYMPH NODE, 4R RIGHT DISTAL PARATRACHEAL, BIOPSY:
-ONE ANTRHACOTIC LYMPH NODE, NEGATIVE FOR TUMOR(0/1)
- B. LYMPH NODE, 4 L LEFT DISTAL PARATRACHEAL, BIOPSY:
-ONE ANTRHACOTIC LYMPH NODE, NEGATIVE FOR TUMOR(0/1)
- C. LYMPH NODE, LEVEL 7, BIOPSY:
-ONE ANTRHACOTIC LYMPH NODE, NEGATIVE FOR TUMOR(0/1)
- D. LYMPH NODE, 2R RIGHT PROXIMAL PARATRACHEAL, BIOPSY:
-ONE ANTRHACOTIC LYMPH NODE, NEGATIVE FOR TUMOR(0/1)
- E. LUNG, RIGHT UPPER LOBE, LOBECTOMY:
- ADENOCARCINOMA, POORLY DIFFERENTIATED
- MARGINS NEGATIVE
- FOUR HILAR LYMPH NODES, NEGATIVE FOR TUMOR (0/4)
- FOCAL PLEURAL FIBROSIS
-FOCAL ATYPICAL ALVEOLAR CELL HYPERPLASIA
- SEE SYNOPTIC REPORT

SYNOPTIC REPORT - LUNG

Specimens Involved

Specimens: A: 4R RIGHT DISTAL PARATRACHEAL
B: 4L LEFT DISTAL PARATRACHEAL
C: LEVEL 7
D: 2R RIGHT PROXIMAL PARATRACHEAL
E: RIGHT UPPER LOBE

Surgical Procedure: Lobectomy

[page 4 of 4]
Laterality: Right
Tumor Site: Upper lobe
Tumor Location: mid lung field
Tumor Size: Greatest diameter: 2cm
Additional dimensions: 1.7cm x 1.5cm

WHO CLASSIFICATION

Adenocarcinoma
Histologic Grade: G3: Poorly differentiated
Angiolymphatic Invasion: Absent
Bronchial Margins: Bronchial margins uninvolved
Tumor Distance from margin: 4cm
Visceral Pleural Involvement: Absent
Satellite Tumor(s): Absent
Lymph Node Involvement: N1: Ipsilateral Hilar and/or Peribronchial (levels 10-14)
Negative 0 / 4
N2: Ipsilateral Mediastinal and/or Subcarinal (Levels 1-9)
Negative 0 / 3
N3: Contralateral Mediastinal/Hilar, Scalene or Supraclavicular
Negative 0 / 1
Non-Neoplastic Lung: Pneumonia
Additional Pathologic Findings: AAH
Pathological Staging (pTNM): pT 1 N 0 M X

Source: NCI Genomic Data Commons file a1df4af8-936e-4de6-b69e-dc667afcec8e (TCGA-73-4666.4AB3BC9E-68AE-4C85-9A2A-11EAD25EE142.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).